Somatic mutation profile of tumor specimen TCGA-VD-A8KD-01A (aliquot TCGA-VD-A8KD-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KD, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.4 years (26,457 days).
Specimen TCGA-VD-A8KD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9da29c81-32ec-4a59-bcc9-73b449e02a8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KD-10A (Blood Derived Normal), aliquot TCGA-VD-A8KD-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76d6c811-c89c-4a04-bf62-c1bb82f27d8c

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Splice Region 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCB4 | c.1888G>T p.D630Y | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568763104, COSV53793606, COSV53801055; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLCB4 | c.1889A>T p.D630V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555839474; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CGNL1 | c.3533G>A p.R1178Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs757609826; called by muse, mutect2, varscan2
- DNER | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370587377; called by muse, mutect2, varscan2
- FBLN7 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs937294316, COSV55615841; called by muse, mutect2
- PRKCB | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100332745; called by muse, mutect2, varscan2
- ADAMTS4 | c.1269T>G p.C423W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP192 | c.6506G>T p.W2169L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPVL | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2
- IL12RB2 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, varscan2
- KDM3B | c.3201G>A p.E1067= | Splice Region (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- PRDM8 | c.848T>A p.L283H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- SLC22A5 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD4 | c.2848T>G p.C950G | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CTTNBP2NL | c.1617T>C p.T539= | Silent (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- GRID2 | c.2868C>T p.N956= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs775585013; called by muse, mutect2, varscan2
- IFNLR1 | c.912G>A p.P304= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as rs543005854; called by muse, mutect2, varscan2
- PTK7 | c.2091C>G p.P697= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- RPS25 | c.174C>G p.L58= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- TIMM50 | chr19:39480713 del TGCGGCAATCCGCCCG | 5'Flank (DEL) | VAF 8/21 reads (38%) | called by mutect2, varscan2
